Somatic mutation profile of tumor specimen 0DOG3K from CCDI case PBCCNN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.2 years (2,617 days).
Specimen 0DOG3K: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dcf34b05-9713-4111-a15c-af4ffe60d7f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOG31 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b527fc5c-e884-4af7-9341-eedec7df8e6d

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 3, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MMP14 | c.1690C>T p.R564C | Missense Mutation (SNP) | VAF 36/336 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs369565852, COSV61289002; called by muse, mutect2, varscan2
- PLK2 | c.323A>G p.Y108C | Missense Mutation (SNP) | VAF 143/464 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368502101; called by muse, mutect2, varscan2
- S100A16 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 56/488 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.489); catalogued as rs773071655, COSV64182898; called by muse, mutect2, varscan2
- SMOC2 | c.874G>A p.A292T (on ENST00000356284 / NM_001166412.2; = p.A303T on NM_022138.3) | Missense Mutation (SNP) | VAF 43/790 reads (5%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100634995; called by muse, mutect2
- TNXB | c.9134G>A p.R3045H (on ENST00000647633; = p.R2798H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/1188 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.062); catalogued as rs372230994; called by muse, mutect2
- TSHZ3 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 23/415 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99550432; called by muse, mutect2
- UNKL | c.5C>G p.P2R | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs752597860; called by muse, mutect2, varscan2
- ABCA3 | c.4903T>G p.F1635V | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCND1 | c.590C>A p.S197Y | Missense Mutation (SNP) | VAF 13/259 reads (5%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.582); called by muse, mutect2
- NFATC2 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 16/522 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- PCDHGB5 | c.1897G>A p.A633T | Missense Mutation (SNP) | VAF 37/560 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.393); called by muse, mutect2
- PXDC1 | c.45C>G p.F15L | Missense Mutation (SNP) | VAF 44/554 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.48); called by muse, mutect2
- SGK1 | c.1055A>T p.H352L | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZC3H12B | c.1582A>T p.I528F | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.368); called by muse, mutect2
- CCDC187 | c.2859C>T p.D953= (on ENST00000638797 / NM_001378188.1; = p.D855= on NM_001291516.1) | Silent (SNP) | VAF 70/316 reads (22%) | catalogued as rs988640069; called by muse, mutect2, varscan2
- SEPTIN14 | c.711C>T p.S237= | Silent (SNP) | VAF 12/292 reads (4%) | called by muse, mutect2
- SHMT2 | c.798G>A p.S266= | Silent (SNP) | VAF 50/498 reads (10%) | catalogued as rs2229715; called by muse, mutect2
- ARHGEF9 | chrX:63755123 C>T | 5'Flank (SNP) | VAF 36/221 reads (16%) | called by muse, mutect2, varscan2
- TCEAL4 | c.-82C>T | 5'UTR (SNP) | VAF 65/131 reads (50%) | called by muse, mutect2, varscan2
